Somatic mutation profile of tumor specimen TCGA-EM-A1CW-01A (aliquot TCGA-EM-A1CW-01A-21D-A13W-08) from TCGA case TCGA-EM-A1CW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.0 years (14,263 days).
Specimen TCGA-EM-A1CW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fcd8692-12e5-4355-a398-1bad81295721.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A1CW-10A (Blood Derived Normal), aliquot TCGA-EM-A1CW-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/972f8cbb-8df6-4ed1-8f6b-a625e0247a7c

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDOB | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 101/387 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV66398090; called by muse, mutect2, varscan2
- GRIA2 | c.84G>C p.Q28H | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.961); catalogued as COSV52394837, COSV52401238; called by muse, mutect2, varscan2
- MTMR11 | c.1390G>T p.D464Y (on ENST00000439741 / NM_001145862.2; = p.D392Y on NM_181873.3) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54965867; called by muse, mutect2, varscan2
- OR2M3 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 127/498 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV71759105; called by muse, mutect2, varscan2
- PARD3 | c.152T>G p.L51W | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60752886; called by muse, mutect2, varscan2
- FNTB | c.124dup p.T42Nfs*53 | Frame Shift Ins (INS) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- LRP11 | c.760del p.V254Wfs*3 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
